HCMI case HCM-BROD-0001-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4829dd8c-5445-41b3-ae37-bbcc333e8c9e

Demographics
Sex at birth: female; Race: white; Year of birth: 1963; Vital status: Dead; Days to death: 1,011 days (2.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C79.3; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 47.4 years (17,316 days); AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1a; Tumor grade: GX; Prior malignancy: no; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Oxaliplatin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Days to treatment start: 53 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 53 days; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 889 days (2.4 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 889 days (2.4 years).
- Days to follow up: 1,011 days (2.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79.8 kg; Height: 165 cm; BMI: 29.3.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Rectal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0001-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0001-C18-06A-02-S1-HE: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 35; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 55; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0001-C18-06A-02-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample HCM-BROD-0001-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0001-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Air-Liquid Interface Organoid; Preservation method: Frozen; Passage count: 24.
